MMRF case MMRF_1983 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/bbf6251c-8009-4daf-8499-5b7fe7de66f5

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.5 years (20,987 days); ISS stage: I; Days to last known disease status: 991 days (2.7 years); Days to last follow up: 991 days (2.7 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 5.71 g/L; Immunoglobulin A 3.27 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 1.6 µg/mL; Hemoglobin 8.18 mmol/L; Leukocytes 9.8 ×10⁹/L; Absolute Neutrophil 9.2 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.48 mmol/L; Albumin 47 g/L; Total Protein 7.3 g/dL; Glucose 4.4 mmol/L.
- Day 107: Serum Free Immunoglobulin Light Chain, Kappa 4.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Hemoglobin 8.43 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 4.57 mmol/L.
- Day 137 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.636 mg/dL; Immunoglobulin G 3.66 g/L; Immunoglobulin A 1.23 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 101 µmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 5.9 g/dL; Glucose 5.72 mmol/L.
- Day 258: Serum Free Immunoglobulin Light Chain, Kappa 2.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.87 mg/dL; Immunoglobulin G 3.48 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 102 µmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 4.51 mmol/L.
- Day 326 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 4.33 g/L; Immunoglobulin A 1.37 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 6.3 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Albumin 44 g/L; Glucose 8.25 mmol/L.
- Day 554 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.95 mg/dL; Immunoglobulin G 4.11 g/L; Immunoglobulin A 2.65 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 5 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.48 mmol/L; Glucose 5.67 mmol/L.
- Day 647 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 10.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Immunoglobulin G 4.17 g/L; Immunoglobulin A 3.35 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 8.74 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 5.72 mmol/L.
- Day 786 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 12.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 3.79 g/L; Immunoglobulin A 4.8 g/L; Immunoglobulin M 0.18 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.53 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 4.57 mmol/L.
- Day 991 (ECOG 0): M Protein 0.75 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Immunoglobulin A 4.93 g/L; Immunoglobulin M 0.15 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 282 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.89 mmol/L.

Other clinical attributes
- Day 1: Weight: 72 kg; Height: 177 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1983_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1983_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
